Surgical pathology report (de-identified scan), TCGA case TCGA-BR-7717, project TCGA-STAD (Stomach Adenocarcinoma), tissue source site Asterand, specimen TCGA-BR-7717-01A (Primary Tumor).

[page 1 of 2]
TCGA Pathology Reports

Asterand Case ID	Open Clinica Subject ID	TCGA	Gross Description	Microscopic Description	Diagnosis Details
		BR-7717			

[page 2 of 2]
Formatted Path Report

STOMACH TISSUE CHECKLIST

Specimen type: Gastrectomy
Tumor site: Stomach
Tumor size: 5 x 4.5 x 1 cm
Tumor features: Ulcerated
Histologic type:
Adenocarcinoma
Histologic grade: Moderately differentiated
Tumor extent: Adjacent structures (specify) - lesser omentum
Lymph nodes: 2/8 positive for metastasis (Intraabdominal 2/8)
Lymphatic invasion: Not specified
Venous invasion: Not specified
Perineural invasion: Not specified
Margins: Not specified
Evidence of neo-adjuvant treatment: Not specified
Additional pathologic findings: Not specified
Comments: None

Date of Procurement

Journal Pre-proof

Source: NCI Genomic Data Commons file f4eee62a-ecb2-407f-b16d-628679e7d173 (TCGA-BR-7717.EF3ED902-E805-4453-9EB3-37399E51CDEF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).